CCDI case PBBWRM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a49415a5-73f9-4a6a-9e95-d9c3a1ee5a61

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 7.2 years (2,622 days).

Biospecimens (2 samples)
- Sample 0DJO4N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJO5D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
